Surgical pathology report (de-identified scan), TCGA case TCGA-DJ-A1QI, project TCGA-THCA (Thyroid Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DJ-A1QI-01A (Primary Tumor).

[page 1 of 3]
Diagnostic Discrepancy		☒
HIIPA Discrepancy		☒

Date of Procedure:
Date of Receipt:
Date of Report:
Account #:
Billing Type:
Additional Copy to:

Clinical Diagnosis & History:

History right thyroid nodule leading to PTC on FNA.

Specimens Submitted:

- 1: SP: Rule out parathyroid (fs)
- 2: THYROID; TOTAL THYROIDECTOMY:

DIAGNOSIS:

1. PARATHYROID, SIDE UNSPECIFIED; BIOPSY (FS):
-PARATHYROID TISSUE, SLIGHTLY HYPERCELLULAR, 0.3 CM.

ICD-0-3

Carcinoma, papillary, thyroid 8260/3

Site: thyroid, NOS C73.9 per 3/14/11

2. THYROID; TOTAL THYROIDECTOMY::

Tumor Type:
Papillary carcinoma, classical type

Histologic Grade:
Well differentiated

Mitotic Activity:
Mild to moderate
1/10 HPFs

Tumor Necrosis:
Not identified

Other Tumor Features:
Calcification of non-psammoma type
Psammoma bodies

Tumor Location:
Right lobe

Tumor Size:
Greatest diameter is 3.0 cm.

Tumor Encapsulation:
Partially surrounded

Blood Vessel Invasion:
Not identified

Extrathyroid Extension:
Not identified

Surgical Margins:
Free of tumor

Tumor Multicentricity:

[page 2 of 3]
Six papillary microcarcinomas, in both lobes and isthmus, ranging in size from 0.08 to 0.6 cm in greatest dimension

Non-Neoplastic Thyroid:
Exhibits nodular hyperplasia

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Special Studies:

Result	Special Stain	Comment
	RECUT	

Gross Description:

1) The specimen is received fresh, labeled "rule out parathyroid". It consists of one fragment of tan-pink fibrotic tissue measuring 0.3 x 0.3 x 0.2 cm and weighs 3 mg. The specimen is entirely submitted for frozen section.

Summary of sections:
FSC-frozen section control

2) The specimen is received fresh, labeled "Total thyroidectomy" and consists of a thyroid weighing 26.5g. The right lobe measures 6.0 x 2.5 x 2.5 cm, the left lobe measures 4.0 x 2.5 x 1.1 cm and the isthmus measures 2.0 x 2.0 x 0.6 cm. The external surface is covered by a thin fibrous capsule. The posterior surface of the specimen is inked black, and the anterior is inked blue. Sectioning reveals a 3.0 x 2.5 x 2.5 cm pink-tan nodule in the right lobe. The nodule abuts the anterior and posterior capsules and is focally cystic. Further sectioning reveals two firm white nodules in the isthmus measuring 0.3 x 0.2 x 0.2 and 0.6 x 0.5 x 0.5 cm. Both nodules are abutting the anterior surface. The remaining thyroid parenchyma is red tan and beefy. Representative sections of the specimen are submitted for TPS, and a photograph has been taken. The remaining tissue is serially sectioned and entirely submitted.

Summary of sections:
N - nodule
RL - right lobe
LL - left lobe
I1--smaller isthmus nodule
I2--larger isthmus nodule
IS - isthmus

Summary of Sections:

Part 1: SP: Rule out parathyroid (fs)

Block	Sect. Site	PCs
1	FSC	1

Part 2: THYROID; TOTAL THYROIDECTOMY:

Block	Sect. Site	PCs
3	I	3
1	I1	2
1	I2	2

[page 3 of 3]
7	LL	10
8	N	10
6	RL	8

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1. FROZEN SECTION DIAGNOSIS: SP: Rule out parathyroid (fs): Parathyroid tissue. (REDACTED)
PERMANENT DIAGNOSIS: Same.

Source: NCI Genomic Data Commons file 2b72fb33-a79a-433d-9e1c-d3b5b3676bdd (TCGA-DJ-A1QI.D81A9CFF-AF3D-4657-9B75-41E72E084286.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).